Somatic mutation profile of tumor specimen TCGA-XU-A92X-01A (aliquot TCGA-XU-A92X-01A-11D-A423-09) from TCGA case TCGA-XU-A92X, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 18.0 years (6,572 days).
Specimen TCGA-XU-A92X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f2c5fa5-a1d0-4588-bd75-23f246df6acb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92X-10A (Blood Derived Normal), aliquot TCGA-XU-A92X-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3cfad8f-5e31-4937-b93e-1c762ff0b6c2

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PWWP3A | c.1975G>T p.V659L (on ENST00000627377; = p.V658L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967539074; called by muse, varscan2
- ZNF790 | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs1437385910; called by muse, mutect2, varscan2
- MED6 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO5 | c.2508T>C p.V836= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- STARD5 | c.225A>G p.L75= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
